Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3681, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3681-01A (Primary Tumor).

Diagnosis:

Right-sided hemicolectomy preparation with a cecal carcinoma, 5 cm in size at its maximum diameter, characterized histologically as a poorly differentiated colorectal adenocarcinoma.

Invasive tumor spread as far as the level of the subserosa and adjoining fatty tissue.

Oral and aboral resection margin and also greater omentum tumor-free.

Appendix with evidently postinflammatory fibrosis of the wall.

Two of 16 mesocolic and mesenteric lymph nodes with metastases of the cecal carcinoma confined to the lymph nodes. Other lymph nodes with uncharacteristic reactive lesions.

Tumor stage thus pT3 pN1 (2/16) L0, V0; G3

Source: NCI Genomic Data Commons file a7944a23-de7c-474c-87e1-210e4b751d28 (TCGA-AA-3681.2485FB59-2E7A-4C9B-B8CF-3A553C953A21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).